CCDI case PBCCRT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/ae1b7a39-be82-483e-8587-f03b02d00c81

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Adrenal cortical carcinoma: ICD-O-3 morphology code: 8370/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.8 years (649 days).

Biospecimens (3 samples)
- Sample 0DOV8K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOV90: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOV97: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
